Gene-level copy-number profile of tumor specimen TCGA-55-7281-01A from TCGA case TCGA-55-7281, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.8 years (25,870 days).
Specimen TCGA-55-7281-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.dbab9576-bfee-4005-99ea-d8ffd3dbb189.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7281-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9eaa99a1-3971-4ef3-b5ef-dd16ee7d1012

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 4; copy number 2: 400; copy number 3: 12,124; copy number 4: 26,606; copy number 5: 4,821; copy number 6: 14,253; copy number 8: 1,602.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7281-01A-11D-2035-01): tumor purity 0.42, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:110,662,644–111,562,517, 1 gene (within-gene range 0–5): IMMP2L.
- chr7:111,091,006–111,411,883, 3 genes: LRRN3, AC003989.2, AC003989.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
